Somatic mutation profile of tumor specimen TCGA-24-2261-01A (aliquot TCGA-24-2261-01A-01W-0722-08) from TCGA case TCGA-24-2261, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 76.4 years (27,897 days).
Specimen TCGA-24-2261-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ef35ee08-e250-4544-b424-e3b7c2dfd854.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-24-2261-11A (Solid Tissue Normal), aliquot TCGA-24-2261-11A-01W-0722-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/18846441-9ac9-4ec9-be7b-6b6fd402626c

The open-access MAF lists 56 somatic variants for this specimen: 40 protein-altering or splice-affecting, 16 silent.
By variant classification: Missense Mutation 35, Silent 16, Nonsense Mutation 3, Splice Region 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.488A>G p.Y163C | Missense Mutation (SNP) | VAF 87/140 reads (62%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs148924904, CM942135, COSV52663142, COSV52676381; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AKR1B1 | c.338C>T p.P113L | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.956); catalogued as rs768419303, COSV53647605; called by muse, mutect2, varscan2
- ASXL3 | c.1087G>A p.G363S | Missense Mutation (SNP) | VAF 18/26 reads (69%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as COSV52483104; called by muse, mutect2, varscan2
- CACNA1C | c.3261A>T p.Q1087H | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.766); catalogued as COSV59784446; called by muse, mutect2, varscan2
- CAV2 | c.448C>T p.R150* | Nonsense Mutation (SNP) | VAF 20/332 reads (6%) | catalogued as rs547905225, COSV56064400; called by muse, mutect2
- COMMD1 | c.176T>A p.L59H | Missense Mutation (SNP) | VAF 20/117 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1171830370, COSV61281757; called by muse, mutect2, varscan2
- CSMD3 | c.3113C>A p.S1038* (on ENST00000297405 / NM_001363185.1; = p.S934* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 90/371 reads (24%) | catalogued as COSV99838696; called by muse, mutect2, varscan2
- CSPG4 | c.3589G>A p.V1197I | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs774099952, COSV57899615; called by muse, mutect2, varscan2
- DGKK | c.2778G>C p.L926F | Missense Mutation (SNP) | VAF 24/260 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65709714; called by muse, mutect2
- DIO3 | c.371A>T p.D124V | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs755573757, COSV63774823; called by muse, mutect2, varscan2
- DIO3 | c.763G>A p.G255S | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100832154; called by muse, mutect2, varscan2
- DOCK10 | c.5890C>T p.R1964W | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs779364831, COSV51431205; called by muse, mutect2, varscan2
- FRMPD3 | c.3061G>A p.E1021K | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.102); catalogued as COSV99346600; called by muse, mutect2, varscan2
- FRYL | c.4324C>A p.L1442M | Missense Mutation (SNP) | VAF 9/198 reads (5%) | SIFT tolerated (0.29); PolyPhen probably damaging (1); catalogued as COSV99977371; called by muse, mutect2
- GP2 | c.280C>A p.R94S | Missense Mutation (SNP) | VAF 52/112 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56897281; called by muse, mutect2, varscan2
- GPS2 | c.716_719del p.T239Rfs*105 | Frame Shift Del (DEL) | VAF 23/91 reads (25%) | catalogued as rs758044036; called by mutect2, pindel, varscan2
- H2BC9 | c.5C>T p.P2L | Missense Mutation (SNP) | VAF 30/99 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as rs1379959298, COSV55101236; called by muse, mutect2, varscan2
- IRX2 | c.1173C>A p.N391K | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.162); catalogued as COSV100121804; called by muse, mutect2, varscan2
- JMJD6 | c.185G>T p.R62L | Missense Mutation (SNP) | VAF 42/50 reads (84%) | SIFT tolerated (0.07); PolyPhen benign (0.022); catalogued as COSV57976492; called by muse, mutect2, varscan2
- LGR6 | c.1137C>T p.I379= (on ENST00000367278 / NM_001017403.1; = p.I327= on NM_021636.3) | Splice Region (SNP) | VAF 4/22 reads (18%) | catalogued as rs563721511, COSV55158212; called by muse, mutect2
- MARK1 | c.2164C>T p.R722* | Nonsense Mutation (SNP) | VAF 7/235 reads (3%) | catalogued as rs901442620, COSV100857114; called by muse, mutect2
- MME | c.308G>T p.R103L | Missense Mutation (SNP) | VAF 91/914 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.16); catalogued as COSV64706789, COSV64711544; called by muse, mutect2, varscan2
- NBEAL1 | c.6140C>T p.S2047L | Missense Mutation (SNP) | VAF 33/282 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781656581, COSV68917210; called by muse, mutect2, varscan2
- NGEF | c.1334A>G p.K445R | Missense Mutation (SNP) | VAF 75/140 reads (54%) | SIFT tolerated (0.5); PolyPhen benign (0.011); catalogued as rs1559192177, COSV50966276; called by muse, mutect2, varscan2
- NRXN3 | c.547G>A p.G183S (on ENST00000557594 / NM_001272020.2; = p.G815S on NM_004796.6) | Missense Mutation (SNP) | VAF 77/376 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs746751046, COSV55363459; called by muse, mutect2, varscan2
- OR2L13 | c.778C>T p.R260W | Missense Mutation (SNP) | VAF 24/282 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.054); catalogued as rs202188433, COSV63549839; called by muse, mutect2
- RAET1E | c.178C>T p.L60F | Missense Mutation (SNP) | VAF 10/107 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); catalogued as COSV61722294; called by muse, mutect2, varscan2
- RAI14 | c.2330C>T p.A777V | Missense Mutation (SNP) | VAF 35/264 reads (13%) | SIFT tolerated (0.87); PolyPhen possibly damaging (0.842); catalogued as COSV54305344; called by muse, mutect2, varscan2
- RAVER1 | c.761C>T p.A254V | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.99); catalogued as rs755887145, COSV53346789; called by muse, mutect2, varscan2
- RBM46 | c.1568G>A p.R523Q | Missense Mutation (SNP) | VAF 30/570 reads (5%) | SIFT tolerated, low confidence (0.87); PolyPhen benign (0); catalogued as rs755052565, COSV55977620; called by muse, mutect2
- RUNDC3B | c.1130G>A p.R377Q | Missense Mutation (SNP) | VAF 31/270 reads (11%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.557); catalogued as rs769895514, COSV56697679; called by muse, mutect2, varscan2
- S1PR1 | c.790G>A p.V264I | Missense Mutation (SNP) | VAF 103/220 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.216); catalogued as COSV59512501; called by muse, mutect2, varscan2
- SAP130 | c.2044C>A p.P682T | Missense Mutation (SNP) | VAF 46/230 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.701); catalogued as COSV52104242; called by muse, mutect2, varscan2
- SF1 | c.541G>A p.G181R | Missense Mutation (SNP) | VAF 271/392 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57115024; called by muse, mutect2, varscan2
- SPRR2A | c.213C>A p.S71R | Missense Mutation (SNP) | VAF 185/973 reads (19%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.305); catalogued as COSV66991593; called by muse, mutect2, varscan2
- SYCP3 | c.157C>T p.R53C | Missense Mutation (SNP) | VAF 19/346 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs754706600, COSV57148492; called by muse, mutect2
- USP49 | c.445C>T p.R149C | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs761240031, COSV51901825; called by muse, mutect2, varscan2
- ZDHHC15 | c.478C>T p.P160S | Missense Mutation (SNP) | VAF 60/331 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.893); catalogued as COSV64904102; called by muse, mutect2, varscan2
- ZMIZ1 | c.889G>A p.A297T | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.858); catalogued as COSV57899767; called by muse, mutect2, varscan2
- MUC3A | c.7256C>G p.T2419S | Missense Mutation (SNP) | VAF 53/343 reads (15%) | SIFT tolerated, low confidence (0.42); called by muse, mutect2, varscan2
- ADCY9 | c.2130G>A p.S710= | Silent (SNP) | VAF 11/119 reads (9%) | catalogued as rs199753697, COSV53582834; called by muse, mutect2, varscan2
- CSMD3 | c.3114A>T p.S1038= (on ENST00000297405 / NM_001363185.1; = p.S934= on NM_052900.3) | Silent (SNP) | VAF 83/354 reads (23%) | catalogued as COSV99838693; called by muse, varscan2
- DOCK3 | c.5094G>C p.L1698= | Silent (SNP) | VAF 14/35 reads (40%) | catalogued as COSV56506222, COSV56550317, COSV56555385; called by muse, mutect2, varscan2
- FMN2 | c.3810C>A p.G1270= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as COSV60459647; called by muse, mutect2, varscan2
- FRAS1 | c.9015G>A p.Q3005= | Silent (SNP) | VAF 17/435 reads (4%) | catalogued as COSV99353702; called by muse, mutect2
- HSF5 | c.702C>T p.S234= | Silent (SNP) | VAF 24/177 reads (14%) | catalogued as COSV60420263; called by muse, mutect2, varscan2
- LRIT2 | c.1530C>T p.T510= | Silent (SNP) | VAF 85/152 reads (56%) | catalogued as rs1484848366, COSV60567241; called by muse, mutect2
- MAGED1 | c.885C>G p.L295= | Silent (SNP) | VAF 19/37 reads (51%) | catalogued as COSV58517159; called by muse, mutect2, varscan2
- MYC | c.648C>T p.F216= (on ENST00000377970; = p.F231= on NM_002467.6) | Silent (SNP) | VAF 9/64 reads (14%) | catalogued as COSV52377047, COSV52381060; called by muse, mutect2, varscan2
- PTPRH | c.1647G>A p.R549= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as rs574069561, COSV54751020; called by muse, mutect2, varscan2
- RNF148 | c.843T>C p.H281= | Silent (SNP) | VAF 24/531 reads (5%) | catalogued as COSV100411652, COSV57387099; called by muse, mutect2
- SDK1 | c.3036C>T p.Y1012= | Silent (SNP) | VAF 10/92 reads (11%) | catalogued as rs373825888; called by muse, mutect2
- SOGA3 | c.1974G>C p.L658= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as COSV64109235; called by muse, mutect2, varscan2
- SPTLC2 | c.1348A>C p.R450= | Silent (SNP) | VAF 45/168 reads (27%) | catalogued as COSV53643882; called by muse, mutect2, varscan2
- ST8SIA6 | c.837C>G p.T279= | Silent (SNP) | VAF 18/352 reads (5%) | catalogued as COSV101112167; called by muse, mutect2
- TMEM192 | c.78C>A p.A26= | Silent (SNP) | VAF 26/408 reads (6%) | catalogued as COSV100122150; called by muse, mutect2
